Gene-level copy-number profile of tumor specimen TCGA-29-1705-01A from TCGA case TCGA-29-1705, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 48.0 years (17,530 days).
Specimen TCGA-29-1705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c848015b-7d16-4074-9253-1d4dcc070a70.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1705-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3252329b-8336-4e19-b3a6-8dc68228461c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 19,601; copy number 2: 32,122; copy number 3: 6,658; copy number 4: 785; copy number 5: 505; copy number 6: 43; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1705-01A-01D-0559-01): tumor purity 0.79, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.
- chr9:21,367,424–30,575,012, 95 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 549 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:87,867,601–88,328,025, 4 genes, copy number 6: AC005066.1, DCAF4L2, AC037450.1, MMP16.
- chr8:88,396,437–88,486,094, 2 genes, copy number 6: RNA5SP272, AC090568.1.
- chr8:109,362,461–120,813,359, 96 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:121,380,137–145,066,685, 447 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,207. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
